Somatic mutation profile of tumor specimen ALCH-B1NU-TTP1-A (aliquot ALCH-B1NU-TTP1-A-1-0-D-A76C-36) from ALCHEMIST case ALCH-B1NU, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.1 years (25,980 days).
Specimen ALCH-B1NU-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 64100783-333d-4463-9f6b-470d718c1487.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1NU-NB1-A (Blood Derived Normal), aliquot ALCH-B1NU-NB1-A-1-0-D-A76C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/334ad902-0e80-4bf5-8d39-779d33a0dd32

The open-access MAF lists 407 somatic variants for this specimen: 250 protein-altering or splice-affecting, 95 silent, 62 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 209, Silent 95, Intron 29, Nonsense Mutation 22, RNA 10, 5'Flank 7, Splice Site 6, 3'UTR 6, 3'Flank 5, Frame Shift Ins 5, 5'UTR 4, In Frame Del 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 56/472 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC1 | c.4016G>C p.G1339A | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.57); catalogued as COSV60679640; called by muse, mutect2, varscan2
- ACADM | c.1173G>A p.M391I | Missense Mutation (SNP) | VAF 24/189 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as COSV100897836, COSV63720180; called by muse, mutect2, varscan2
- ADORA2A | c.664C>T p.R222W | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs781339364, COSV58380268; called by muse, mutect2, varscan2
- ALOX15B | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1203473195, COSV101205720; called by muse, varscan2
- ANKRD52 | c.2518G>C p.E840Q | Missense Mutation (SNP) | VAF 26/215 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.314); catalogued as rs1342879473; called by muse, mutect2, varscan2
- ARAP1 | c.1598C>T p.S533F (on ENST00000393609 / NM_001040118.2; = p.S288F on NM_015242.4) | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV61990132; called by muse, mutect2, varscan2
- ARMC3 | c.680T>A p.M227K | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.259); catalogued as COSV53068649, COSV99957546; called by muse, mutect2, varscan2
- ATM | c.6178C>T p.R2060C | Missense Mutation (SNP) | VAF 49/417 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs587778078, COSV53732724; ClinVar: not provided / uncertain significance; called by muse, mutect2, varscan2
- BICD2 | c.1975C>T p.Q659* | Nonsense Mutation (SNP) | VAF 18/131 reads (14%) | catalogued as COSV100794072; called by muse, mutect2, varscan2
- C11orf1 | c.235G>A p.D79N | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.948); catalogued as rs1555163330, COSV52789849, COSV99500512; called by muse, mutect2, varscan2
- C16orf96 | c.2500G>A p.E834K | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs762558204; called by muse, mutect2, varscan2
- CACHD1 | c.1345G>A p.D449N | Missense Mutation (SNP) | VAF 40/265 reads (15%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.971); catalogued as rs764619717; called by muse, mutect2, varscan2
- CACNG8 | c.361C>G p.L121V | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.388); catalogued as COSV54415032; called by muse, mutect2, varscan2
- CASR | c.2707G>C p.D903H (on ENST00000490131; = p.D980H on NM_000388.4) | Missense Mutation (SNP) | VAF 54/324 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.875); catalogued as COSV56138907; called by muse, mutect2, varscan2
- CC2D2A | c.4609dup p.S1537Kfs*9 | Frame Shift Ins (INS) | VAF 18/109 reads (17%) | catalogued as rs1259255310; called by mutect2, pindel, varscan2
- CCDC173 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs750324427, COSV69573527; called by muse, varscan2
- CD1C | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.271); catalogued as rs867887479; called by muse, mutect2
- CENPE | c.4176G>A p.M1392I | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.073); catalogued as rs1409554865; called by muse, mutect2
- CFAP65 | c.2785C>A p.P929T | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778431096; called by muse, mutect2, varscan2
- CFAP77 | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 39/166 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as rs750627151, COSV58011328; called by muse, mutect2, varscan2
- CPSF6 | c.37G>A p.D13N | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs1410283336, COSV57013997; called by muse, mutect2, varscan2
- CTF1 | c.130C>A p.L44M | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53064122; called by muse, mutect2, varscan2
- DCAF6 | c.821C>T p.S274L | Missense Mutation (SNP) | VAF 49/338 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs773326971; called by muse, mutect2, varscan2
- DCHS1 | c.5069C>G p.S1690C | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs1023242194, COSV55035657, COSV55041860; called by muse, mutect2, varscan2
- DDB1 | c.608A>G p.N203S | Missense Mutation (SNP) | VAF 70/407 reads (17%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs755753291; called by muse, mutect2, varscan2
- DOCK2 | c.1288C>G p.L430V | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.043); catalogued as rs370264550, COSV56952151; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOT1L | c.3064G>A p.E1022K | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.131); catalogued as rs571375214; called by muse, mutect2, varscan2
- ELL2 | c.1255G>A p.D419N | Missense Mutation (SNP) | VAF 32/270 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs369188132; called by muse, varscan2
- ENDOD1 | c.114C>G p.F38L | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99566529; called by muse, mutect2, varscan2
- FAM83B | c.26C>T p.S9L | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60923848; called by muse, mutect2, varscan2
- FBLN1 | c.2034G>A p.M678I | Missense Mutation (SNP) | VAF 23/212 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.278); catalogued as rs764937908; called by muse, mutect2, varscan2
- FBN1 | c.6449G>A p.R2150H | Missense Mutation (SNP) | VAF 38/381 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs794728250; called by muse, mutect2, varscan2
- FOXE1 | c.824C>A p.S275Y | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1174448034; called by muse, mutect2, varscan2
- GCM2 | c.345G>A p.K115= | Splice Region (SNP) | VAF 72/393 reads (18%) | catalogued as rs1040019354; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GLI1 | c.1483C>T p.L495F | Missense Mutation (SNP) | VAF 32/258 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as COSV57368420; called by muse, mutect2, varscan2
- GNAI3 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.027); catalogued as rs1407780609; called by muse, mutect2, varscan2
- GUCY2F | c.407C>T p.S136L | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.523); catalogued as rs1053471613, COSV54297945, COSV54306707; called by muse, mutect2, varscan2
- HSH2D | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as rs903174575; called by muse, mutect2, varscan2
- HYAL4 | c.701C>G p.S234C | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as rs1415114385; called by muse, mutect2, varscan2
- IFNGR1 | c.332C>G p.S111C | Missense Mutation (SNP) | VAF 36/202 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62989751; called by muse, mutect2, varscan2
- INSYN2A | c.543G>A p.M181I | Missense Mutation (SNP) | VAF 31/260 reads (12%) | SIFT tolerated (0.76); PolyPhen benign (0.022); catalogued as rs752031911, COSV99731927; called by muse, mutect2, varscan2
- KARS1 | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 66/442 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.391); catalogued as rs886052328; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIAA1549L | c.937C>G p.P313A (on ENST00000321505; = p.P610A on NM_012194.3) | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV99683709; called by muse, mutect2, varscan2
- KIF20B | c.1562C>T p.S521L | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV53316982; called by muse, varscan2
- KRT75 | c.1051G>A p.V351I | Missense Mutation (SNP) | VAF 66/425 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.101); catalogued as rs781249370, COSV52872296; called by muse, mutect2, varscan2
- LAMA5 | c.4741G>A p.E1581K | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs748303724; called by muse, mutect2, varscan2
- LRPAP1 | c.329G>A p.R110K | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201485938; called by muse, mutect2
- MARCHF6 | c.1861C>T p.Q621* | Nonsense Mutation (SNP) | VAF 11/103 reads (11%) | catalogued as COSV56884130; called by muse, mutect2
- METTL9 | c.670G>C p.D224H | Missense Mutation (SNP) | VAF 48/383 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV63961146; called by muse, mutect2, varscan2
- MORN1 | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 15/200 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.394); catalogued as COSV58101376; called by muse, mutect2
- MUC16 | c.4487C>T p.S1496F | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.641); catalogued as rs761036288; called by muse, mutect2, varscan2
- NCOR1 | c.5948C>T p.A1983V | Missense Mutation (SNP) | VAF 20/183 reads (11%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs763880485; called by muse, mutect2, varscan2
- NDUFB7 | c.34G>A p.D12N | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as COSV53108084; called by muse, mutect2, varscan2
- NIN | c.3892G>A p.E1298K | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.616); catalogued as rs1226292752; called by muse, mutect2, varscan2
- NRTN | c.374T>C p.V125A | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as rs748453602, COSV54607643; called by muse, mutect2, varscan2
- OCSTAMP | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as rs1250392442, COSV54097466; called by muse, mutect2
- OTUB1 | c.19C>T p.Q7* | Nonsense Mutation (SNP) | VAF 10/73 reads (14%) | catalogued as COSV56839412; called by muse, mutect2, varscan2
- PDE1C | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 14/191 reads (7%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.216); catalogued as rs764049622, COSV68804176; called by muse, mutect2
- PEX6 | c.2896G>A p.E966K | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV55107174; called by muse, mutect2, varscan2
- PLA2G2F | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as rs762216339, COSV64279787; called by muse, mutect2, varscan2
- QDPR | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 22/424 reads (5%) | SIFT tolerated (0.44); PolyPhen benign (0.043); catalogued as rs1200947456; called by muse, mutect2
- SETD2 | c.5016-1G>C p.X1672_splice | Splice Site (SNP) | VAF 17/141 reads (12%) | catalogued as COSV57450773; called by muse, mutect2, varscan2
- SIK2 | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765252862; called by muse, mutect2, varscan2
- SIKE1 | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 33/226 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.013); catalogued as rs771964431; called by muse, mutect2, varscan2
- SLC6A2 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 44/293 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.481); catalogued as rs147833183; called by muse, mutect2, varscan2
- SPTA1 | c.5710G>T p.E1904* | Nonsense Mutation (SNP) | VAF 28/450 reads (6%) | catalogued as COSV63760561; called by muse, mutect2
- TACSTD2 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 38/247 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV64667355; called by muse, mutect2, varscan2
- TCTE1 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 58/435 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.04); catalogued as rs746423492, COSV65255618; called by muse, mutect2, varscan2
- TEX55 | c.860C>T p.S287F | Missense Mutation (SNP) | VAF 17/182 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as rs1399451559; called by muse, mutect2
- THOC2 | c.1564C>T p.R522C | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.043); catalogued as rs1479506968; called by muse, mutect2, varscan2
- TOPORS | c.2387G>A p.R796Q | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); catalogued as rs751624872, COSV104422895; called by muse, mutect2, varscan2
- TUBB2B | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.292); catalogued as rs974931581, COSV99455272; called by muse, mutect2, varscan2
- TYMP | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.74); PolyPhen benign (0.022); catalogued as rs755917995; called by muse, mutect2, varscan2
- USP25 | c.1514C>T p.S505L | Missense Mutation (SNP) | VAF 27/343 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV99583835; called by muse, mutect2
- USP39 | c.862C>T p.R288* | Nonsense Mutation (SNP) | VAF 61/384 reads (16%) | catalogued as rs748592767, COSV60383237; called by muse, mutect2, varscan2
- VEZT | c.64G>A p.D22N | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54145975; called by muse, mutect2, varscan2
- VPS13D | c.7129C>G p.Q2377E | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50681346; called by muse, mutect2, varscan2
- ZFYVE26 | c.2758A>G p.M920V | Missense Mutation (SNP) | VAF 22/334 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.152); catalogued as rs1455130234; called by muse, mutect2
- ZFYVE27 | c.359C>T p.S120F | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as COSV61746395; called by muse, mutect2, varscan2
- ZHX3 | c.1816C>T p.H606Y | Missense Mutation (SNP) | VAF 33/245 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.281); catalogued as rs764944666; called by muse, mutect2, varscan2
- ZNF471 | c.227C>T p.T76M | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.131); catalogued as rs749785140, COSV57289644; called by muse, mutect2
- ZNF512B | c.2152G>A p.E718K | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as rs1156946240; called by muse, varscan2
- ZNF730 | c.325G>T p.E109* | Nonsense Mutation (SNP) | VAF 8/64 reads (13%) | catalogued as COSV74168058; called by muse, mutect2
- ZNF99 | c.1137C>A p.S379R | Missense Mutation (SNP) | VAF 24/227 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.158); catalogued as COSV68055383; called by muse, mutect2, varscan2
- ZSCAN29 | c.2461C>G p.H821D | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.012); catalogued as rs746459746; called by muse, mutect2, varscan2
- ZZEF1 | c.1042G>C p.E348Q | Missense Mutation (SNP) | VAF 31/321 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV67557899; called by muse, mutect2
- ABCA8 | c.3821G>A p.R1274K | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ACO2 | c.1483-1G>C p.X495_splice | Splice Site (SNP) | VAF 13/90 reads (14%) | called by muse, mutect2, varscan2
- ACTG2 | c.360G>A p.M120I | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- ADGRL3 | c.1933G>A p.E645K (on ENST00000506720 / NM_001322402.2; = p.E577K on NM_015236.6) | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- AHNAK2 | c.11183G>C p.S3728T | Missense Mutation (SNP) | VAF 30/194 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- AHNAK2 | c.1501G>C p.E501Q | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- ALPI | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 24/202 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.77); called by muse, varscan2
- ANXA6 | c.1222C>T p.H408Y | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- APBB1IP | c.746G>C p.R249T | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ASB5 | c.964C>A p.L322M | Missense Mutation (SNP) | VAF 45/306 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.611); called by muse, mutect2, varscan2
- ASPM | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by muse, mutect2
- ATP6V0E2 | c.211G>T p.E71* (on ENST00000425642; = p.E120* on NM_145230.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 16/130 reads (12%) | called by muse, mutect2, varscan2
- B4GALT4 | c.915A>C p.L305F | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BTBD8 | c.2989G>C p.E997Q (on ENST00000636805 / NM_001376131.1; = p.E484Q on NM_015237.4) | Missense Mutation (SNP) | VAF 34/204 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- BTN3A3 | c.942G>C p.W314C | Missense Mutation (SNP) | VAF 50/347 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- BUB3 | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- CAPN3 | c.907G>C p.D303H | Missense Mutation (SNP) | VAF 43/256 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- CASS4 | c.152G>C p.W51S | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC141 | c.1677A>C p.Q559H | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CCDC178 | c.2068G>C p.E690Q (on ENST00000383096 / NM_001105528.3; = p.E652Q on NM_198995.3) | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- CCT8 | c.598G>C p.D200H | Missense Mutation (SNP) | VAF 4/71 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2
- CCT8 | c.482C>G p.S161* | Nonsense Mutation (SNP) | VAF 8/67 reads (12%) | called by muse, mutect2, varscan2
- CD109 | c.3997C>G p.L1333V | Missense Mutation (SNP) | VAF 27/229 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- CHD8 | c.4717C>T p.Q1573* (on ENST00000646647 / NM_001170629.2; = p.Q1294* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 16/119 reads (13%) | called by muse, mutect2, varscan2
- CHST10 | c.642G>T p.R214S | Missense Mutation (SNP) | VAF 42/275 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- CLTCL1 | c.2959G>A p.E987K | Missense Mutation (SNP) | VAF 26/279 reads (9%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.796); called by muse, mutect2
- CUL2 | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- CYP19A1 | c.1026G>C p.E342D | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2
- CYRIB | c.841-1G>A p.X281_splice | Splice Site (SNP) | VAF 15/97 reads (15%) | called by muse, mutect2, varscan2
- DHX29 | c.283G>C p.E95Q | Missense Mutation (SNP) | VAF 22/188 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DHX33 | c.1305G>A p.Q435= | Splice Region (SNP) | VAF 11/90 reads (12%) | called by muse, mutect2
- DOT1L | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- DPP9 | c.1414T>C p.F472L (on ENST00000598800; = p.F501L on NM_139159.5) | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.67); PolyPhen benign (0.001); called by muse, mutect2
- DSCAM | c.4223C>G p.S1408C | Missense Mutation (SNP) | VAF 35/260 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DYRK1A | c.1437C>G p.F479L | Missense Mutation (SNP) | VAF 23/199 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- DZIP3 | c.2735G>A p.W912* | Nonsense Mutation (SNP) | VAF 29/212 reads (14%) | called by muse, mutect2, varscan2
- EARS2 | c.743C>G p.S248C | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- EDRF1 | c.1993C>T p.Q665* (on ENST00000356792 / NM_001202438.2; = p.Q631* on NM_015608.2) | Nonsense Mutation (SNP) | VAF 50/384 reads (13%) | called by muse, mutect2, varscan2
- EFCAB8 | c.866C>A p.P289H | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2
- ESYT1 | c.949C>T p.Q317* | Nonsense Mutation (SNP) | VAF 25/256 reads (10%) | called by muse, mutect2, varscan2
- EXOSC6 | c.13C>T p.H5Y | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- F5 | c.1744G>A p.E582K | Missense Mutation (SNP) | VAF 32/406 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.009); called by muse, mutect2
- FASTKD5 | c.350T>C p.V117A | Missense Mutation (SNP) | VAF 30/190 reads (16%) | SIFT tolerated (0.75); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FGB | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 27/179 reads (15%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- FSIP2 | c.1744G>A p.E582K | Missense Mutation (SNP) | VAF 38/224 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- GAK | c.1495G>A p.D499N | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- GBP6 | c.1495G>C p.E499Q | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.987); called by muse, mutect2
- GLI3 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 35/346 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- GLIPR1L2 | c.418G>C p.E140Q | Missense Mutation (SNP) | VAF 26/242 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.586); called by muse, mutect2, varscan2
- GOLGA6L22 | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 20/276 reads (7%) | SIFT tolerated (0.07); called by muse, mutect2, varscan2
- GOPC | c.70del p.A24Pfs*47 | Frame Shift Del (DEL) | VAF 12/89 reads (13%) | called by mutect2, pindel, varscan2
- GPR156 | c.318dup p.I107Dfs*70 | Frame Shift Ins (INS) | VAF 43/331 reads (13%) | called by mutect2, pindel, varscan2
- GPR83 | c.473C>G p.S158* | Nonsense Mutation (SNP) | VAF 14/114 reads (12%) | called by muse, mutect2, varscan2
- H1-5 | c.320C>G p.S107C | Missense Mutation (SNP) | VAF 21/215 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- ID4 | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2
- ILVBL | c.1298_1301+2del p.X433_splice | Splice Site (DEL) | VAF 43/156 reads (28%) | called by mutect2, pindel, varscan2
- INPP5E | c.1379C>G p.S460C | Missense Mutation (SNP) | VAF 40/213 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- INSRR | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- KCNB2 | c.2233T>C p.S745P | Missense Mutation (SNP) | VAF 8/238 reads (3%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); called by muse, mutect2
- KDELR2 | c.517G>C p.E173Q | Missense Mutation (SNP) | VAF 43/494 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.601); called by muse, mutect2
- KEAP1 | c.286C>T p.H96Y | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KHDC1 | c.402C>A p.F134L (on ENST00000370384 / NM_001251874.2; = p.F61L on NM_030568.5) | Missense Mutation (SNP) | VAF 27/202 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- KIAA1549L | c.1583C>G p.T528S (on ENST00000321505; = p.T825S on NM_012194.3) | Missense Mutation (SNP) | VAF 22/194 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF6 | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLKB1 | c.12C>G p.F4L | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2
- KRT74 | c.1475C>G p.S492C | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- LRRC42 | c.488C>T p.S163L | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- LRRTM1 | c.1350G>A p.W450* | Nonsense Mutation (SNP) | VAF 23/99 reads (23%) | called by muse, mutect2, varscan2
- MAPK8 | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- MBD6 | c.2350C>T p.P784S | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.703); called by muse, mutect2
- MCOLN1 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- MFAP1 | c.166G>C p.E56Q | Missense Mutation (SNP) | VAF 44/423 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- MGA | c.804G>C p.Q268H | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.461); called by muse, varscan2
- MGA | c.969G>C p.K323N | Missense Mutation (SNP) | VAF 32/243 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, varscan2
- MLXIP | c.40C>A p.R14S | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MRM1 | c.1028C>T p.S343L | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MRPL17 | c.335A>C p.N112T | Missense Mutation (SNP) | VAF 13/300 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.101); called by muse, mutect2
- MTO1 | c.2092G>C p.E698Q (on ENST00000370300 / NM_133645.3; = p.E673Q on NM_012123.4) | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MYT1L | c.1156G>T p.E386* | Nonsense Mutation (SNP) | VAF 45/191 reads (24%) | called by muse, mutect2, varscan2
- NCBP1 | c.2029delinsATA p.D677Ifs*17 | Frame Shift Ins (INS) | VAF 35/163 reads (21%) | called by pindel, varscan2*
- NEFH | c.1408G>C p.V470L | Missense Mutation (SNP) | VAF 50/352 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- NONO | c.415C>G p.L139V | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- NOTCH2 | c.3627C>A p.F1209L | Missense Mutation (SNP) | VAF 47/288 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- NOX4 | c.1516-5G>C | Splice Region (SNP) | VAF 11/79 reads (14%) | called by muse, mutect2, varscan2
- NPRL3 | c.1077T>G p.H359Q (on ENST00000611875 / NM_001077350.3; = p.H334Q on NM_001039476.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/192 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- NRAP | c.1286_1297del p.T429_A432del (on ENST00000359988 / NM_001322945.2; = p.T394_A397del on NM_006175.4) | In Frame Del (DEL) | VAF 36/302 reads (12%) | called by mutect2, pindel
- NYAP2 | c.191_196del p.K64_R65del | In Frame Del (DEL) | VAF 18/152 reads (12%) | called by mutect2, pindel, varscan2
- OR2T10 | c.293G>C p.G98A | Missense Mutation (SNP) | VAF 52/333 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- OR4D1 | c.157T>C p.C53R | Missense Mutation (SNP) | VAF 21/186 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- OSBP2 | c.1033G>C p.E345Q | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- PCLO | c.7037C>T p.S2346F | Missense Mutation (SNP) | VAF 24/227 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- PDS5B | c.1903G>A p.D635N | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.843); called by muse, mutect2
- PGBD1 | c.1694G>C p.R565T | Missense Mutation (SNP) | VAF 24/170 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- PGGT1B | c.167C>G p.S56C | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- PHLDB3 | c.577C>A p.L193I | Missense Mutation (SNP) | VAF 35/181 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PLXNC1 | c.4603-1G>A p.X1535_splice | Splice Site (SNP) | VAF 15/104 reads (14%) | called by muse, mutect2, varscan2
- POLR2D | c.106G>T p.E36* | Nonsense Mutation (SNP) | VAF 33/179 reads (18%) | called by muse, mutect2, varscan2
- PRSS16 | c.1241C>T p.S414L | Missense Mutation (SNP) | VAF 31/268 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- PURB | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- RAB22A | c.452dup p.N151Kfs*7 | Frame Shift Ins (INS) | VAF 13/90 reads (14%) | called by mutect2, pindel, varscan2
- RAB6B | c.314C>G p.S105C | Missense Mutation (SNP) | VAF 44/244 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- RBL2 | c.2592G>C p.L864F | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RIF1 | c.6002G>C p.G2001A | Missense Mutation (SNP) | VAF 32/250 reads (13%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RLIM | c.1332dup p.G445Wfs*9 | Frame Shift Ins (INS) | VAF 18/81 reads (22%) | called by mutect2, pindel, varscan2
- RPS7 | c.571G>C p.E191Q | Missense Mutation (SNP) | VAF 22/196 reads (11%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- RRP9 | c.763C>T p.Q255* | Nonsense Mutation (SNP) | VAF 24/140 reads (17%) | called by muse, mutect2, varscan2
- RSRC1 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- RYR1 | c.5968G>C p.E1990Q | Missense Mutation (SNP) | VAF 45/253 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- RYR2 | c.8044G>A p.E2682K | Missense Mutation (SNP) | VAF 44/455 reads (10%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- RYR3 | c.2842C>T p.L948F | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SCRN1 | c.1198G>A p.D400N | Missense Mutation (SNP) | VAF 88/304 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SETDB1 | c.3211G>A p.E1071K | Missense Mutation (SNP) | VAF 30/270 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- SH3YL1 | c.983G>T p.R328L | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.565); called by muse, mutect2, varscan2
- SIGLEC5 | c.1211C>G p.S404C | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- SLC13A5 | c.899A>G p.K300R | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC36A1 | c.705C>G p.I235M | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- SLC41A1 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 56/487 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- SLC45A4 | c.2317G>A p.D773N (on ENST00000517878 / NM_001286646.2; = p.L719= on NM_001080431.2) | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- SLFN5 | c.2275G>C p.E759Q | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- SLIT2 | c.370C>T p.L124F | Missense Mutation (SNP) | VAF 51/316 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- SOS2 | c.2968G>A p.E990K | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- SPTBN4 | c.6748G>C p.E2250Q | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- SV2B | c.1051G>C p.E351Q | Missense Mutation (SNP) | VAF 19/204 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.37); called by muse, mutect2
- SVEP1 | c.10238-1G>C p.X3413_splice | Splice Site (SNP) | VAF 37/174 reads (21%) | called by muse, mutect2, varscan2
- SWT1 | c.347C>T p.S116F | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- SYNE1 | c.2461G>C p.E821Q (on ENST00000367255 / NM_182961.4; = p.E828Q on NM_033071.3) | Missense Mutation (SNP) | VAF 47/307 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SYNE2 | c.6715G>C p.D2239H | Missense Mutation (SNP) | VAF 46/387 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- SYNE2 | c.12317G>A p.R4106K | Missense Mutation (SNP) | VAF 50/458 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYT11 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 29/460 reads (6%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.453); called by muse, mutect2
- TAF2 | c.1674G>C p.Q558H | Missense Mutation (SNP) | VAF 37/280 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- TANC2 | c.1235G>A p.R412K | Missense Mutation (SNP) | VAF 27/268 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- TCHH | c.1813G>A p.E605K | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- TENM2 | c.2932T>G p.L978V (on ENST00000518659 / NM_001122679.2; = p.L746V on NM_001080428.3) | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT tolerated (0.82); PolyPhen probably damaging (0.997); called by muse, mutect2
- TK1 | c.544C>T p.H182Y | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- TNFRSF17 | c.103C>G p.L35V | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT tolerated (0.76); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TNFRSF8 | c.1300G>C p.E434Q | Missense Mutation (SNP) | VAF 38/253 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- TOP2B | c.4363C>G p.Q1455E (on ENST00000264331 / NM_001330700.2; = p.Q1450E on NM_001068.3) | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated, low confidence (0.78); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- TPO | c.2739C>A p.D913E | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.037); called by mutect2, varscan2
- TRAPPC10 | c.1312C>G p.Q438E | Missense Mutation (SNP) | VAF 24/206 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- TRIM26 | c.655G>T p.E219* | Nonsense Mutation (SNP) | VAF 39/292 reads (13%) | called by muse, mutect2, varscan2
- TRIR | c.92C>T p.S31L | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.042); called by muse, varscan2
- TRMT1 | c.917_941del p.Y306Sfs*67 | Frame Shift Del (DEL) | VAF 14/99 reads (14%) | called by mutect2, pindel
- TTC30A | c.860C>T p.P287L | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- UEVLD | c.267G>C p.L89F | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- UNC13B | c.3276G>C p.K1092N | Missense Mutation (SNP) | VAF 37/232 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- UPB1 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 32/223 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- USE1 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- USF3 | c.4019C>T p.S1340L | Missense Mutation (SNP) | VAF 23/171 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USH2A | c.12607C>T p.Q4203* | Nonsense Mutation (SNP) | VAF 28/264 reads (11%) | called by muse, mutect2, varscan2
- USP34 | c.454G>C p.D152H | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- USP9X | c.4103G>C p.R1368T | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- VAV2 | c.1168C>T p.Q390* (on ENST00000371850 / NM_001134398.2; = p.Q385* on NM_003371.4) | Nonsense Mutation (SNP) | VAF 32/234 reads (14%) | called by muse, mutect2, varscan2
- VPS53 | c.1840G>A p.D614N (on ENST00000571805 / NM_001366253.2; = p.D585N on NM_018289.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- VPS8 | c.1195C>T p.H399Y (on ENST00000625842 / NM_001349294.1; = p.H397Y on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- WDFY4 | c.7967_7972del p.C2656_A2657del | In Frame Del (DEL) | VAF 20/148 reads (14%) | called by mutect2, pindel, varscan2
- WHRN | c.2401G>A p.D801N | Missense Mutation (SNP) | VAF 41/356 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- WIPI1 | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2
- ZNF32 | c.125C>T p.S42L | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); called by muse, mutect2
- ZNF518A | c.1544C>T p.S515L | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2
- ZNF658 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF729 | c.3265T>C p.S1089P | Missense Mutation (SNP) | VAF 37/284 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF839 | c.97C>T p.Q33* (on ENST00000558850 / NM_001267827.1; = p.Q149* on NM_018335.5) | Nonsense Mutation (SNP) | VAF 7/86 reads (8%) | called by muse, mutect2
- ZRANB3 | c.2050T>A p.C684S | Missense Mutation (SNP) | VAF 96/582 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ACCSL | c.1590C>T p.L530= | Silent (SNP) | VAF 10/69 reads (14%) | called by muse, mutect2, varscan2
- ACSBG2 | c.1228C>T p.L410= | Silent (SNP) | VAF 40/257 reads (16%) | catalogued as COSV53123243, COSV53127362; called by muse, mutect2, varscan2
- AHNAK2 | c.5310G>C p.L1770= | Silent (SNP) | VAF 31/183 reads (17%) | catalogued as rs375405949, COSV60914972; called by muse, mutect2, varscan2
- AKR1C1 | c.210A>C p.A70= | Silent (SNP) | VAF 23/216 reads (11%) | called by muse, mutect2, varscan2
- AL441992.2 | c.498G>A p.T166= | Silent (SNP) | VAF 17/122 reads (14%) | catalogued as rs748064840; called by muse, mutect2, varscan2
- ALDH3A2 | c.366G>A p.L122= | Silent (SNP) | VAF 30/215 reads (14%) | called by muse, mutect2, varscan2
- ALK | c.2421G>A p.V807= | Silent (SNP) | VAF 39/243 reads (16%) | called by muse, mutect2, varscan2
- ASB8 | c.531C>G p.V177= | Silent (SNP) | VAF 15/146 reads (10%) | called by muse, mutect2, varscan2
- ASPSCR1 | c.483G>T p.L161= | Silent (SNP) | VAF 8/46 reads (17%) | called by muse, mutect2, varscan2
- ASPSCR1 | c.1014G>A p.A338= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as rs1191066325, COSV60731437; called by muse, mutect2, varscan2
- CAMK2B | c.1887G>A p.Q629= | Silent (SNP) | VAF 26/272 reads (10%) | catalogued as rs369973326; called by muse, mutect2
- CBX4 | c.63C>T p.I21= | Silent (SNP) | VAF 16/72 reads (22%) | called by muse, mutect2, varscan2
- CCDC186 | c.1239C>G p.L413= | Silent (SNP) | VAF 21/181 reads (12%) | called by muse, mutect2, varscan2
- CCDC81 | c.822C>T p.V274= (on ENST00000445632 / NM_001156474.2; = p.V184= on NM_021827.4) | Silent (SNP) | VAF 18/148 reads (12%) | called by muse, varscan2
- CFD | c.75G>T p.R25= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs1279328101; called by mutect2, varscan2
- CPXM2 | c.1581C>T p.Y527= | Silent (SNP) | VAF 14/140 reads (10%) | catalogued as rs200492616; called by muse, mutect2
- CRY2 | c.480G>A p.L160= | Silent (SNP) | VAF 12/74 reads (16%) | called by muse, mutect2
- CYP19A1 | c.1164G>C p.V388= | Silent (SNP) | VAF 46/391 reads (12%) | called by muse, mutect2, varscan2
- CYP2W1 | c.603C>T p.L201= | Silent (SNP) | VAF 18/137 reads (13%) | called by muse, mutect2, varscan2
- DNAJC1 | c.123C>G p.A41= | Silent (SNP) | VAF 11/98 reads (11%) | called by muse, varscan2
- DST | c.19206A>G p.A6402= (on ENST00000361203 / NM_001374722.1; = p.A4099= on NM_015548.5) | Silent (SNP) | VAF 22/208 reads (11%) | called by muse, mutect2, varscan2
- DYRK4 | c.1479C>T p.V493= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as rs1412574025, COSV99155556; called by muse, mutect2, varscan2
- E4F1 | c.456G>A p.A152= | Silent (SNP) | VAF 16/108 reads (15%) | catalogued as rs760502409; called by muse, mutect2, varscan2
- EIF2AK4 | c.477G>A p.Q159= | Silent (SNP) | VAF 20/190 reads (11%) | catalogued as COSV55471304; called by muse, mutect2, varscan2
- EPHB4 | c.1002G>C p.L334= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as rs1163523115; called by muse, mutect2, varscan2
- EPHX4 | c.582C>T p.F194= | Silent (SNP) | VAF 19/144 reads (13%) | catalogued as rs868866714, COSV64889530; called by muse, mutect2, varscan2
- EXOG | c.675C>T p.P225= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs758843527, COSV55064290; called by muse, varscan2
- FADS2 | c.1270C>T p.L424= | Silent (SNP) | VAF 11/79 reads (14%) | called by muse, mutect2
- FAT4 | c.5316T>C p.N1772= | Silent (SNP) | VAF 18/99 reads (18%) | called by muse, mutect2, varscan2
- FLT1 | c.2763C>G p.L921= | Silent (SNP) | VAF 41/296 reads (14%) | called by muse, mutect2, varscan2
- FOXN1 | c.138C>T p.F46= | Silent (SNP) | VAF 19/145 reads (13%) | called by muse, mutect2, varscan2
- FSHR | c.732G>A p.L244= | Silent (SNP) | VAF 56/388 reads (14%) | catalogued as rs779103606, COSV58628964; called by muse, mutect2, varscan2
- GAREM2 | c.579G>A p.A193= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as rs1426548871; called by muse, mutect2, varscan2
- GK2 | c.1311A>T p.L437= | Silent (SNP) | VAF 15/139 reads (11%) | catalogued as rs910556956; called by muse, mutect2, varscan2
- GUCY2D | c.1161C>T p.V387= | Silent (SNP) | VAF 17/110 reads (15%) | catalogued as rs1287668105, COSV99643911; called by muse, mutect2, varscan2
- H6PD | c.2238C>T p.V746= | Silent (SNP) | VAF 32/236 reads (14%) | called by muse, mutect2, varscan2
- HOXD11 | c.468C>A p.G156= | Silent (SNP) | VAF 10/82 reads (12%) | called by muse, mutect2, varscan2
- HSD11B1 | c.819G>A p.R273= | Silent (SNP) | VAF 14/410 reads (3%) | catalogued as rs1351519112; called by muse, mutect2
- INPP5F | c.573G>A p.Q191= | Silent (SNP) | VAF 17/161 reads (11%) | called by muse, mutect2, varscan2
- IPO13 | c.1692C>A p.P564= | Silent (SNP) | VAF 23/118 reads (19%) | called by muse, mutect2, varscan2
- KCNQ3 | c.498C>A p.I166= | Silent (SNP) | VAF 55/493 reads (11%) | called by muse, mutect2, varscan2
- KIF26B | c.4869C>T p.T1623= | Silent (SNP) | VAF 16/73 reads (22%) | called by muse, mutect2, varscan2
- KPNA7 | c.646C>T p.L216= | Silent (SNP) | VAF 7/60 reads (12%) | called by muse, mutect2, varscan2
- LAMC2 | c.2037C>G p.L679= | Silent (SNP) | VAF 35/368 reads (10%) | called by muse, mutect2
- LYST | c.7014C>T p.V2338= | Silent (SNP) | VAF 20/250 reads (8%) | called by muse, mutect2
- MAGI3 | c.300C>G p.L100= | Silent (SNP) | VAF 27/203 reads (13%) | catalogued as rs1476677109; called by muse, mutect2, varscan2
- MAN2A2 | c.3402C>T p.D1134= | Silent (SNP) | VAF 21/197 reads (11%) | catalogued as rs780625069; called by muse, mutect2, varscan2
- MELTF | c.372G>A p.L124= | Silent (SNP) | VAF 12/87 reads (14%) | called by muse, mutect2, varscan2
- MICAL3 | c.5877G>A p.E1959= | Silent (SNP) | VAF 43/202 reads (21%) | called by muse, mutect2, varscan2
- MROH2B | c.4209G>C p.V1403= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as rs1313857431; called by muse, mutect2, varscan2
- MROH9 | c.1317G>A p.P439= | Silent (SNP) | VAF 19/182 reads (10%) | catalogued as rs757784456, COSV63012551; called by muse, mutect2, varscan2
- MSR1 | c.1092G>A p.E364= | Silent (SNP) | VAF 40/260 reads (15%) | called by muse, mutect2, varscan2
- NEXN | c.1233G>T p.L411= | Silent (SNP) | VAF 25/197 reads (13%) | called by muse, mutect2, varscan2
- NF1 | c.4494C>T p.F1498= (on ENST00000358273 / NM_001042492.3; = p.F1477= on NM_000267.3) | Silent (SNP) | VAF 29/180 reads (16%) | catalogued as CD000977; called by muse, mutect2, varscan2
- NLRP4 | c.1530G>A p.K510= | Silent (SNP) | VAF 14/228 reads (6%) | catalogued as rs756247466, COSV56723615; called by muse, mutect2
- OLFML2B | c.1533G>A p.G511= | Silent (SNP) | VAF 16/204 reads (8%) | called by muse, mutect2
- OR13G1 | c.834G>A p.V278= | Silent (SNP) | VAF 40/340 reads (12%) | catalogued as rs759475889, COSV62943280, COSV62944042; called by muse, mutect2, varscan2
- OR2L13 | c.264G>A p.Q88= | Silent (SNP) | VAF 33/295 reads (11%) | catalogued as rs12738485; called by muse, mutect2, varscan2
- OR5R1 | c.249G>A p.V83= | Silent (SNP) | VAF 23/172 reads (13%) | catalogued as COSV56572405; called by muse, mutect2, varscan2
- OR8B3 | c.852C>T p.L284= | Silent (SNP) | VAF 30/200 reads (15%) | catalogued as COSV100660338; called by muse, mutect2, varscan2
- OVOL3 | c.252G>T p.L84= (on ENST00000585332; = p.L60= on NM_001302757.1) | Silent (SNP) | VAF 11/108 reads (10%) | catalogued as rs1039387903; called by muse, mutect2, varscan2
- PAPPA | c.1782C>T p.F594= | Silent (SNP) | VAF 50/432 reads (12%) | catalogued as rs189146018; called by muse, mutect2, varscan2
- PKHD1 | c.10212C>T p.I3404= | Silent (SNP) | VAF 10/119 reads (8%) | called by muse, mutect2
- PPP2CA | c.84C>G p.V28= | Silent (SNP) | VAF 30/156 reads (19%) | catalogued as rs779757541; called by muse, mutect2, varscan2
- PPP4R3B | c.1137C>T p.V379= | Silent (SNP) | VAF 8/72 reads (11%) | called by muse, mutect2
- PTPN12 | c.1215C>G p.L405= | Silent (SNP) | VAF 17/64 reads (27%) | called by muse, mutect2, varscan2
- PTPRN2 | c.1485C>T p.L495= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as rs371700295, COSV67034988; called by muse, mutect2, varscan2
- RAB3GAP2 | c.4017G>A p.L1339= | Silent (SNP) | VAF 54/576 reads (9%) | called by muse, mutect2
- RASAL2 | c.1941G>A p.Q647= | Silent (SNP) | VAF 51/317 reads (16%) | called by muse, mutect2, varscan2
- RBCK1 | c.615C>T p.I205= (on ENST00000356286 / NM_031229.4; = p.I163= on NM_006462.6) | Silent (SNP) | VAF 12/56 reads (21%) | called by muse, varscan2
- RNLS | c.15G>A p.L5= | Silent (SNP) | VAF 15/115 reads (13%) | catalogued as COSV59293633; called by muse, mutect2, varscan2
- ROS1 | c.4440C>T p.I1480= | Silent (SNP) | VAF 46/330 reads (14%) | catalogued as COSV63856710; called by muse, mutect2, varscan2
- RTN4RL2 | c.1215C>T p.L405= | Silent (SNP) | VAF 19/71 reads (27%) | catalogued as rs749260825; called by muse, mutect2, varscan2
- SCFD2 | c.1989G>T p.L663= | Silent (SNP) | VAF 28/228 reads (12%) | called by muse, mutect2, varscan2
- SCGB2A2 | c.186G>A p.L62= | Silent (SNP) | VAF 36/297 reads (12%) | called by muse, mutect2, varscan2
- SERPINB13 | c.394C>T p.L132= | Silent (SNP) | VAF 13/127 reads (10%) | called by muse, mutect2, varscan2
- SLITRK2 | c.726C>G p.V242= | Silent (SNP) | VAF 38/148 reads (26%) | catalogued as COSV59427889; called by muse, mutect2, varscan2
- SND1 | c.480G>A p.K160= | Silent (SNP) | VAF 27/228 reads (12%) | called by muse, mutect2, varscan2
- SPAG9 | c.663G>A p.Q221= | Silent (SNP) | VAF 37/291 reads (13%) | catalogued as COSV56238158; called by muse, mutect2, varscan2
- SPEG | c.1470C>G p.L490= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as rs762783602; called by muse, mutect2, varscan2
- SRSF9 | c.135C>G p.L45= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as rs768484451, COSV57584760; called by muse, mutect2, varscan2
- STC1 | c.666G>A p.L222= | Silent (SNP) | VAF 43/293 reads (15%) | called by muse, mutect2, varscan2
- STK19 | c.846C>T p.V282= (on ENST00000375333 / NM_032454.1; = p.V278= on NM_004197.1) | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV64692078; called by muse, mutect2, varscan2
- SYT3 | c.1635C>T p.H545= | Silent (SNP) | VAF 12/115 reads (10%) | catalogued as rs1408316117, COSV58897160; called by muse, mutect2, varscan2
- TAAR9 | c.1005G>A p.S335= | Silent (SNP) | VAF 14/108 reads (13%) | catalogued as rs370306299, COSV71512218; called by muse, mutect2, varscan2
- TMEM102 | c.897C>T p.F299= | Silent (SNP) | VAF 11/66 reads (17%) | called by muse, mutect2, varscan2
- TMEM102 | c.1041C>T p.F347= | Silent (SNP) | VAF 14/71 reads (20%) | called by muse, mutect2, varscan2
- TRIR | c.75G>C p.G25= | Silent (SNP) | VAF 8/86 reads (9%) | called by muse, varscan2
- TTF2 | c.2043A>T p.S681= | Silent (SNP) | VAF 11/81 reads (14%) | called by muse, mutect2
- TVP23B | c.438C>A p.L146= | Silent (SNP) | VAF 29/148 reads (20%) | catalogued as rs898661447; called by muse, mutect2, varscan2
- UXS1 | c.1248G>T p.R416= | Silent (SNP) | VAF 14/107 reads (13%) | catalogued as rs1436523522; called by mutect2, varscan2
- VWA3B | c.2031G>T p.L677= | Silent (SNP) | VAF 13/78 reads (17%) | called by muse, mutect2
- WASHC2C | c.2184C>T p.S728= | Silent (SNP) | VAF 38/339 reads (11%) | catalogued as rs782394171; called by muse, mutect2, varscan2
- ZNF281 | c.591C>G p.L197= | Silent (SNP) | VAF 29/334 reads (9%) | called by muse, mutect2
- ZSCAN31 | c.876G>A p.E292= | Silent (SNP) | VAF 47/203 reads (23%) | catalogued as rs776552125; called by muse, mutect2, varscan2
- ABCC6P2 | n.137C>T | RNA (SNP) | VAF 22/211 reads (10%) | catalogued as rs1347184252; called by muse, mutect2, varscan2
- AC073648.1 | n.300C>T | RNA (SNP) | VAF 48/280 reads (17%) | catalogued as rs760995802; called by muse, mutect2, varscan2
- AC090155.1 | n.134G>C | RNA (SNP) | VAF 17/126 reads (13%) | called by muse, mutect2, varscan2
- ACADSB | c.-4G>A | 5'UTR (SNP) | VAF 22/167 reads (13%) | catalogued as rs766888009; called by muse, mutect2, varscan2
- ANKDD1A | c.1483+999G>A | Intron (SNP) | VAF 11/101 reads (11%) | called by muse, mutect2, varscan2
- AOAH | c.128-3332G>A | Intron (SNP) | VAF 16/161 reads (10%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505347 G>A | 5'Flank (SNP) | VAF 20/196 reads (10%) | called by muse, mutect2
- ARPC3 | c.106+23C>T | Intron (SNP) | VAF 19/162 reads (12%) | called by muse, mutect2, varscan2
- ASH1L | chr1:155562773 G>A | 5'Flank (SNP) | VAF 33/360 reads (9%) | catalogued as rs1215265357; called by muse, mutect2
- CCBE1 | c.*27G>T | 3'UTR (SNP) | VAF 36/250 reads (14%) | catalogued as COSV67951997; called by mutect2, varscan2
- CCSER1 | c.2217+233678C>G | Intron (SNP) | VAF 16/178 reads (9%) | called by muse, mutect2
- CLEC7A | c.492+28C>A | Intron (SNP) | VAF 10/68 reads (15%) | called by muse, mutect2, varscan2
- COPB2 | c.2625+9G>C | Intron (SNP) | VAF 23/191 reads (12%) | called by muse, mutect2, varscan2
- CREB3L2 | c.319+5463C>G | Intron (SNP) | VAF 22/177 reads (12%) | called by muse, mutect2, varscan2
- CXorf38 | c.352-1026C>G | Intron (SNP) | VAF 9/34 reads (26%) | called by muse, mutect2, varscan2
- DCD | c.98-432G>T | Intron (SNP) | VAF 26/188 reads (14%) | called by muse, mutect2, varscan2
- DDX46 | c.1544-325C>T | Intron (SNP) | VAF 32/230 reads (14%) | called by muse, mutect2, varscan2
- DEPDC5 | c.2568-72G>A | Intron (SNP) | VAF 23/171 reads (13%) | called by muse, mutect2, varscan2
- DIO2 | c.*319G>A | 3'UTR (SNP) | VAF 20/148 reads (14%) | catalogued as COSV101375889; called by muse, mutect2, varscan2
- DMPK | c.1648-32C>T | Intron (SNP) | VAF 11/38 reads (29%) | called by muse, mutect2, varscan2
- DOK6 | c.-49C>T | 5'UTR (SNP) | VAF 12/84 reads (14%) | called by muse, mutect2
- FER1L4 | n.3577C>G | RNA (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- GRIN2A | c.2357-12T>C | Intron (SNP) | VAF 24/244 reads (10%) | called by muse, mutect2
- GSK3A | chr19:42226410 C>T | 3'Flank (SNP) | VAF 40/323 reads (12%) | catalogued as rs1181649560; called by muse, mutect2, varscan2
- GVINP1 | n.4088C>G | RNA (SNP) | VAF 23/221 reads (10%) | called by muse, mutect2, varscan2
- HERC2P3 | n.1118C>T | RNA (SNP) | VAF 51/362 reads (14%) | catalogued as rs755098712; called by muse, mutect2, varscan2
- HOXB6 | c.-79+2290C>G | Intron (SNP) | VAF 25/191 reads (13%) | catalogued as rs1244905208; called by muse, mutect2, varscan2
- HSP90B3P | n.21G>A | RNA (SNP) | VAF 80/545 reads (15%) | called by muse, mutect2, varscan2
- IKBIP | c.297+8031G>A | Intron (SNP) | VAF 14/82 reads (17%) | catalogued as rs1328624583, COSV54488714; called by muse, mutect2, varscan2
- KERA | c.*50G>A | 3'UTR (SNP) | VAF 14/90 reads (16%) | catalogued as COSV57132049; called by muse, mutect2, varscan2
- LST1 | c.*20C>T | 3'UTR (SNP) | VAF 7/165 reads (4%) | catalogued as rs1203380119; called by muse, mutect2
- MCFD2 | chr2:46917192 C>G | 5'Flank (SNP) | VAF 46/245 reads (19%) | called by muse, mutect2, varscan2
- MTX1 | chr1:155218042 G>C | 3'Flank (SNP) | VAF 18/168 reads (11%) | called by muse, varscan2
- NCAM1 | chr11:112961405 G>A | 5'Flank (SNP) | VAF 21/189 reads (11%) | catalogued as rs1163176540; called by muse, mutect2, varscan2
- NPL | c.230+226G>T | Intron (SNP) | VAF 32/286 reads (11%) | called by muse, mutect2
- OR2L1P | n.355C>G | RNA (SNP) | VAF 36/378 reads (10%) | called by muse, mutect2
- PDE10A | c.106+91757C>T | Intron (SNP) | VAF 29/191 reads (15%) | called by muse, mutect2, varscan2
- PISD | c.*102C>T | 3'UTR (SNP) | VAF 22/158 reads (14%) | catalogued as rs889666362; called by muse, mutect2, varscan2
- PKD1L2 | n.943C>T | RNA (SNP) | VAF 3/34 reads (9%) | catalogued as rs1316025628; called by muse, mutect2
- PLEKHH1 | c.-1C>T | 5'UTR (SNP) | VAF 14/95 reads (15%) | called by muse, mutect2, varscan2
- PRKAB1 | c.160-796G>A | Intron (SNP) | VAF 16/134 reads (12%) | called by mutect2, varscan2
- PSMB8 | chr6:32844445 G>A | 5'Flank (SNP) | VAF 9/69 reads (13%) | catalogued as rs1422499818; called by muse, mutect2
- RASGRP1 | c.2259+29C>T | Intron (SNP) | VAF 22/272 reads (8%) | called by muse, mutect2
- RASGRP1 | chr15:38565345 G>A | 5'Flank (SNP) | VAF 11/75 reads (15%) | catalogued as rs900561989; called by muse, mutect2, varscan2
- RFPL4AL1 | chr19:55778382 C>T | 3'Flank (SNP) | VAF 38/152 reads (25%) | catalogued as rs1176949286; called by muse, mutect2
- RGS20 | c.510+1378C>A | Intron (SNP) | VAF 13/116 reads (11%) | catalogued as COSV99391703; called by muse, mutect2, varscan2
- RPL39 | c.3+21C>T | Intron (SNP) | VAF 7/23 reads (30%) | called by muse, mutect2, varscan2
- RTCA | c.800-3923G>A | Intron (SNP) | VAF 12/128 reads (9%) | called by muse, mutect2, varscan2
- RUSC1 | c.-86-190dup | Intron (INS) | VAF 30/123 reads (24%) | catalogued as rs761630305; called by mutect2, pindel, varscan2
- SLC11A1 | c.274-32C>G | Intron (SNP) | VAF 16/118 reads (14%) | called by muse, mutect2, varscan2
- SLCO2A1 | chr3:133928354 C>T | 3'Flank (SNP) | VAF 10/52 reads (19%) | catalogued as COSV60486779, COSV60488761; called by muse, mutect2
- SMAD7 | c.-3C>T | 5'UTR (SNP) | VAF 11/70 reads (16%) | called by muse, mutect2, varscan2
- SNORD116-16 | n.12G>A | RNA (SNP) | VAF 38/247 reads (15%) | called by muse, mutect2, varscan2
- TBL2 | chr7:73578580 G>A | 5'Flank (SNP) | VAF 13/79 reads (16%) | catalogued as COSV99979782; called by muse, mutect2, varscan2
- TMCO6 | chr5:140645408 A>G | 3'Flank (SNP) | VAF 23/170 reads (14%) | called by muse, mutect2
- TMEM67 | c.406+32G>C | Intron (SNP) | VAF 18/106 reads (17%) | called by muse, mutect2, varscan2
- TTC39A | c.999+219G>C | Intron (SNP) | VAF 21/142 reads (15%) | called by muse, mutect2, varscan2
- USH1C | c.1285-3865G>A | Intron (SNP) | VAF 32/252 reads (13%) | called by muse, mutect2, varscan2
- Unknown | chr21:16071394 C>T | IGR (SNP) | VAF 15/170 reads (9%) | called by muse, mutect2
- ZBED3 | c.-152-1713G>A | Intron (SNP) | VAF 5/19 reads (26%) | catalogued as rs756698278; called by muse, mutect2
- ZNF497 | c.-111-321C>T | Intron (SNP) | VAF 3/29 reads (10%) | called by muse, mutect2
- ZNF99 | c.*2906C>T | 3'UTR (SNP) | VAF 8/96 reads (8%) | called by muse, mutect2
